Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABKI, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABKI-TTP1-A (Primary Tumor).

Material description

- A) Lobar hilum lymph node
- B) Upper pulmonary lobe, left lung
- C) Lower pulmonary lobe, left lung , lumpectomy
- D) Aortic arc lymph nodes

CDDP-YP-ABKI-01-PR

Macro description

- A) 4 lymph nodes with bigger axis between 0.5 cm and 1 cm of diameter.
- B) 19 x 9 x 4.5 cm pulmonary upper lobe, left lung, with posterior area of thickening and pleural retraction, which corresponds to, when you cut, a whitish nodule with polycyclic margins with bigger axis of 2.4 cm, far 4.6 cm from the margin of bronchial resection. Remaining parenchyma without focal lesions We close off 6 peribronchial lymph nodes (B1 margin of bronco-vascular resection; B2 B4 neofonnation of visceral pleura, B5 parenchyma at distance, B6 peribronchial lymph nodes).
- C) Fragment of pulmonary parenchyma of 3 x 2 x 1.2 cm with nodule with soft margins, whitish, elastic compactness ,with bigger axis of 0.7 cm.
- D) 2 lymph nodes with bigger axis of 2 cm and 1.4 cm.

Micro description

- A) Reactive lymphadenitis with histiocytosis of sinuses and black lung disease. No evidence of metastases.
- B-C) Pulmonary mixed adenocarcinoma, acinar and papillary with focal peripheral aspects of bronchiolo-alveolar adenocarcinoma not mucinous (WHO 1999), moderately differentiated (G2), bifocal. Pleura and remaining parenchyma free of neoplasm. Lymph nodes metastases of adenocarcinoma in 2 of 6 found lymph nodes. Reactive lymphadenitis with histiocytosis of sinuses and black lung disease in the remaining lymph nodes. The neoplasm is extended to the margin of parenchymal resection shown in indian ink in the sample C
- D) Reactive lymphadenitis with histiocytosis of sinuses and black lung disease. No evidence of metastases.

Staging pTNM: p T1 ,N1, M1

ICB-0-3

adenocarcinoma, with mixed subtypes 8255/3
Site: (L) lung, upper lobe C34.1

ICB-10

C34.12

hw
2/10/16

Source: NCI Genomic Data Commons file 5ab40d9b-863d-4343-bdf4-55db023dbd7f (CDDP-ABKI-TTP1.5738A5F4-BA3A-4012-94BA-8D3F0BC11C7F.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).